CCDI case PBCFKU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a29ebd7e-be54-4d2d-a915-0975c4f3d9e8

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (204 days).

Biospecimens (3 samples)
- Sample 0DS06Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS06S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSCOB: Tissue type: Tumor; Specimen type: Solid Tissue.
